Somatic mutation profile of tumor specimen 0065bfd9-e1b9-43a8-9379-9658ba (aliquot 0065bfd9-e1b9-43a8-9379-9658ba_D6_1) from CPTAC case 20CO007, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 0065bfd9-e1b9-43a8-9379-9658ba: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8d405e1-a3af-4d4b-b1fc-b17bfa6571b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 46c880d8-2352-43b5-84cc-acc87c (Blood Derived Normal), aliquot 46c880d8-2352-43b5-84cc-acc87c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/962b69cb-5e1b-42a6-8a29-593af1eee3e1

The open-access MAF lists 277 somatic variants for this specimen: 183 protein-altering or splice-affecting, 60 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 60, Intron 25, Splice Region 5, Nonsense Mutation 5, RNA 4, Frame Shift Del 4, Frame Shift Ins 3, 3'UTR 2, 3'Flank 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 72/270 reads (27%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.4724del p.G1575Vfs*17 | Frame Shift Del (DEL) | VAF 23/156 reads (15%) | catalogued as rs864309545; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 87/343 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 79/308 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs1555526478, CM1210346, COSV52731101, COSV52944837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV53063134; called by muse, mutect2
- ACE | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.456); catalogued as rs988156346; called by muse, mutect2
- ARMC6 | c.197G>T p.G66V (on ENST00000392336; = p.G41V on NM_033415.4) | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99523110; called by muse, mutect2, varscan2
- AVPR1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1321821927, COSV54545511; called by muse, mutect2
- B4GALNT3 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV99842238; called by muse, mutect2, varscan2
- CBARP | c.725C>T p.P242L (on ENST00000382477; = p.P222L on NM_152769.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1309368464; called by muse, mutect2, varscan2
- CCDC87 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1565320513, COSV59579877; called by muse, mutect2
- CDC34 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99296367; called by muse, mutect2, varscan2
- CDH4 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); catalogued as COSV64668888; called by muse, varscan2
- CDYL | c.1706G>T p.R569M (on ENST00000328908 / NM_001368125.1; = p.R515M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100189037; called by muse, mutect2, varscan2
- CNTN5 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.901); catalogued as COSV54341756; called by muse, mutect2, varscan2
- COL22A1 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.514); catalogued as rs1261315047; called by muse, mutect2, varscan2
- CPT1A | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM993447, COSV55760898; called by muse, mutect2, varscan2
- CTNNB1 | c.1958C>A p.T653K | Missense Mutation (SNP) | VAF 133/513 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100846547, COSV62708232; called by muse, mutect2, varscan2
- FGF6 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs370482414; called by muse, mutect2, varscan2
- FOXK2 | c.1649A>G p.Q550R | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs529897705; called by muse, mutect2, varscan2
- FRY | c.2581C>T p.R861W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs772657959, COSV66573664; called by muse, mutect2, varscan2
- FSHR | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 88/388 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100436456; called by muse, mutect2, varscan2
- FTCD | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs750414357; called by muse, varscan2
- GEMIN5 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV53559640; called by muse, mutect2, varscan2
- GUCY1B1 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52373552; called by muse, mutect2, varscan2
- GYG2 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99059662; called by muse, mutect2, varscan2
- HDAC4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as rs139121214; called by muse, varscan2
- HTR3E | c.1018C>A p.P340T (on ENST00000415389 / NM_001256613.1; = p.P355T on NM_182589.2) | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV58948373; called by muse, mutect2, varscan2
- HYDIN | c.7469C>T p.A2490V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs367546874; called by muse, mutect2, varscan2
- IGLON5 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214470700; called by muse, mutect2
- IGLV1-40 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as rs537751449; called by muse, mutect2, varscan2
- ITGB8 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs151014289, COSV56009520; called by muse, varscan2
- ITPK1 | c.777C>A p.D259E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as COSV50893819, COSV99968238; called by muse, mutect2, varscan2
- KCNB2 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.572); catalogued as rs933108759; called by muse, mutect2, varscan2
- KIF2B | c.1626dup p.L543Ifs*18 | Frame Shift Ins (INS) | VAF 18/132 reads (14%) | catalogued as rs745728329; called by mutect2, varscan2
- LCE1C | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.093); catalogued as rs1451932043, COSV64218542; called by muse, mutect2, varscan2
- MAP3K15 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as COSV100135206; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752521574, COSV53797823; called by muse, mutect2, varscan2
- MASP1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1233328546; called by mutect2, varscan2
- MORC2 | c.1604G>A p.R535Q (on ENST00000397641 / NM_001303256.3; = p.R473Q on NM_014941.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs750003469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTTP | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs762413666; called by muse, mutect2, varscan2
- MYH4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs755708452, COSV55113074; called by muse, mutect2, varscan2
- MYH9 | c.5662C>T p.R1888W | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs578002660; called by muse, mutect2, varscan2
- NLGN1 | c.1250del p.N417Ifs*16 | Frame Shift Del (DEL) | VAF 26/237 reads (11%) | catalogued as COSV100849365; called by mutect2, pindel, varscan2
- NOL6 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as rs766771664, COSV99955411; called by muse, mutect2, varscan2
- NOS3 | c.2115C>T p.A705= | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as rs1290430105; called by muse, mutect2, varscan2
- ONECUT1 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1456018098, COSV59947782; called by muse, mutect2, varscan2
- OR4L1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59850215; called by muse, mutect2, varscan2
- PCDH17 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64972520; called by muse, mutect2
- PIK3CA | c.1338G>C p.W446C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56005760; called by muse, mutect2, varscan2
- PNPLA3 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs375342777; called by muse, varscan2
- PPP1R15B | c.1958G>A p.S653N | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762921048; called by muse, mutect2, varscan2
- PTEN | c.413A>C p.Y138S | Missense Mutation (SNP) | VAF 56/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100909436, COSV64306562; called by muse, mutect2, varscan2
- RBL1 | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.024); catalogued as rs1296856560; called by muse, mutect2, varscan2
- RSPH10B | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs374427152; called by mutect2, varscan2
- RYR1 | c.4757C>T p.P1586L | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.727); catalogued as rs752060627, COSV62107365; called by muse, mutect2, varscan2
- RYR2 | c.7069C>A p.P2357T | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV63712618; called by muse, mutect2
- SCN3A | c.3560G>A p.G1187D | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.52); catalogued as COSV51804283; called by muse, mutect2, varscan2
- SIGLEC1 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV52463581; called by muse, mutect2, varscan2
- SLC18A1 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334846206; called by muse, mutect2, varscan2
- SLC4A3 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs746756356, COSV99812439; called by muse, mutect2, varscan2
- SLC6A2 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54921528; called by mutect2, varscan2
- SUSD4 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59557159; called by muse, varscan2
- SYT9 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs568579361, COSV59625619; called by muse, mutect2, varscan2
- TBXA2R | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV64344356; called by muse, mutect2
- TMEM156 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs370274406, COSV60744497; called by muse, mutect2, varscan2
- TTN | c.5800G>T p.D1934Y (on ENST00000591111; = p.D1888Y on NM_003319.4) | Missense Mutation (SNP) | VAF 66/301 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV60020171; called by muse, varscan2
- UNC45B | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745572525, COSV99268852; called by mutect2, varscan2
- UTRN | c.8509A>C p.T2837P | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62312981; called by muse, mutect2, varscan2
- ZFAND4 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs751952776, COSV100763160, COSV60858945; called by muse, mutect2, varscan2
- ZNF662 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs774884680; called by muse, mutect2, varscan2
- ZNF761 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs760993579, COSV61887818; called by muse, mutect2, varscan2
- ZSCAN10 | c.403C>A p.Q135K (on ENST00000252463; = p.Q190K on NM_032805.3) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52971281; called by muse, mutect2, varscan2
- ZSCAN10 | c.172G>A p.E58K (on ENST00000252463; = p.E113K on NM_032805.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52970450; called by muse, mutect2, varscan2
- ACSM4 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR1C | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS19 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- AMPD3 | c.1195A>G p.S399G (on ENST00000396553 / NM_001025389.2; = p.S408G on NM_000480.3) | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3411G>T p.V1137= | Splice Region (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2989T>A p.C997S (on ENST00000611781; = p.C941S on NM_052997.2) | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AOPEP | c.1831A>C p.K611Q (on ENST00000375315 / NM_001193329.1; = p.K512Q on NM_032823.5) | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- APC | c.5762_5763delinsA p.G1921Dfs*49 | Frame Shift Del (DEL) | VAF 61/452 reads (13%) | called by pindel, varscan2*
- AQR | c.3213A>T p.E1071D | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ATG2B | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BABAM2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBS4 | c.1481C>G p.P494R | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BPIFB2 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- C12orf42 | c.612C>A p.S204R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2CD4C | c.254A>C p.Q85P | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CANT1 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC66 | c.1315A>G p.T439A (on ENST00000394672 / NM_001353147.1; = p.T405A on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CDH19 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELA2B | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM3 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CILP | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- COA3 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- COL22A1 | c.4640C>G p.P1547R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.133); called by muse, mutect2
- CPNE1 | c.1136C>T p.A379V (on ENST00000352393; = p.A384V on NM_003915.5) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, varscan2
- CTSC | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLD | c.168dup p.H57Afs*29 | Frame Shift Ins (INS) | VAF 25/240 reads (10%) | called by mutect2, pindel, varscan2
- DAAM2 | c.1914G>T p.E638D | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DENND10 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- DLAT | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG1 | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOK2 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- EIF4ENIF1 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EPB42 | c.229G>T p.A77S (on ENST00000441366 / NM_001114134.2; = p.A107S on NM_000119.3) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ETS2 | c.1199C>G p.A400G | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT3 | c.13114C>T p.P4372S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- FBXL16 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FEM1A | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- G2E3 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- GUF1 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXA11 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- IGKV3D-15 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INTS9 | c.1862A>G p.E621G | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ISLR2 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ITGB8 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- KDM4D | c.449A>C p.K150T | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- KIAA2026 | c.3503C>T p.A1168V | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2026 | c.3061A>G p.T1021A | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- LAMC1 | c.3175C>A p.L1059I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LILRA4 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LPA | c.4505G>A p.C1502Y | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- LRRC7 | c.781C>T p.P261S (on ENST00000651989 / NM_001370785.2; = p.P228S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- LTBP3 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1A | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MARS1 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- MBD3 | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MROH1 | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- MYH15 | c.3367C>A p.L1123I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NAF1 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NCAPD2 | c.3782G>T p.S1261I | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2
- NCK2 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIPAL1 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOS1AP | c.516C>G p.S172R | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- NPHS1 | c.2872G>T p.G958W | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NWD2 | c.4040G>A p.S1347N | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD7B | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- OVCH2 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PATJ | c.4373C>A p.P1458H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PCDHA10 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHF20L1 | c.2601A>T p.Q867H | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PIGO | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, varscan2
- PKD1L1 | c.5474G>T p.G1825V | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PML | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA6 | c.2379G>T p.E793D (on ENST00000414982 / NM_001166111.2; = p.E745D on NM_006702.5) | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRRT4 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PTGIR | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PTPN23 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- RGL1 | c.1195C>T p.R399C (on ENST00000360851 / NM_001297672.2; = p.R434C on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RHBDL1 | c.1106G>C p.G369A (on ENST00000219551 / NM_001318733.2; = p.G304A on NM_001278720.2) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RNF139 | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTL1 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTN3 | c.386dup p.M130Dfs*25 (on ENST00000377819 / NM_001265589.2; = p.M111Dfs*25 on NM_201428.3) | Frame Shift Ins (INS) | VAF 16/161 reads (10%) | called by mutect2, pindel, varscan2
- SAXO2 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCAI | c.1811A>T p.D604V (on ENST00000336505 / NM_001144877.3; = p.D627V on NM_173690.5) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SCARF1 | c.2269G>T p.A757S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SCN10A | c.3644_3646del p.T1215del | In Frame Del (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- SCN5A | c.705G>T p.G235= | Splice Region (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- SEC24A | c.2576G>A p.S859N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, varscan2
- SECISBP2L | c.1958C>A p.A653D (on ENST00000559471 / NM_001193489.2; = p.A608D on NM_014701.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SGO2 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- SLC3A1 | c.1618-3T>A | Splice Region (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- SPHKAP | c.4693G>T p.E1565* | Nonsense Mutation (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- SPSB3 | c.126+4G>A | Splice Region (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- SPSB4 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2
- SYNJ1 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TCERG1 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TICRR | c.5566G>T p.G1856W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- TMC2 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TNRC6C | c.4335G>A p.W1445* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- TNXB | c.2432C>A p.A811D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TRGV4 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WDR11 | c.3494C>A p.A1165E | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by mutect2, varscan2
- ZNF318 | c.6356del p.G2119Afs*2 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | called by mutect2, varscan2
- ZNF362 | c.111C>G p.N37K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF385B | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF396 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF648 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- ZNF697 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF850 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- AASDH | c.837C>A p.S279= | Silent (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- ABHD11 | c.606G>T p.A202= | Silent (SNP) | VAF 19/200 reads (10%) | called by muse, mutect2
- ALG2 | c.426G>T p.L142= | Silent (SNP) | VAF 47/220 reads (21%) | called by muse, mutect2, varscan2
- ARAP3 | c.3759C>T p.G1253= | Silent (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.846G>A p.K282= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- BICC1 | c.1314A>T p.A438= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- BRD2 | c.975G>A p.K325= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- BTBD8 | c.2238G>A p.P746= (on ENST00000636805 / NM_001376131.1; = p.P233= on NM_015237.4) | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as rs373237129; called by muse, mutect2, varscan2
- CALN1 | c.21C>T p.T7= (on ENST00000329008 / NM_001017440.3; = p.T49= on NM_031468.4) | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs544217491, COSV61135996, COSV61141581; called by muse, mutect2, varscan2
- CCDC116 | c.468C>A p.S156= | Silent (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- CCNK | c.1260C>T p.P420= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs753191271; called by muse, mutect2, varscan2
- COL4A1 | c.3771G>C p.G1257= | Silent (SNP) | VAF 111/430 reads (26%) | catalogued as rs759474854; called by muse, mutect2, varscan2
- EFL1 | c.1716A>G p.E572= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- EYS | c.7170C>T p.S2390= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs201364943, COSV65488643; called by muse, mutect2, varscan2
- FIBCD1 | c.1065C>T p.F355= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- FZD7 | c.621C>A p.P207= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV53811614; called by muse, mutect2, varscan2
- GGT6 | c.123G>A p.R41= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- HAUS8 | c.252G>A p.K84= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- HIVEP3 | c.1371C>A p.P457= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- HJV | c.957G>T p.G319= (on ENST00000336751 / NM_213653.4; = p.G206= on NM_145277.5) | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- HPX | c.513C>T p.D171= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- HSD3B2 | c.82C>T p.L28= | Silent (SNP) | VAF 62/279 reads (22%) | called by muse, mutect2, varscan2
- IGLV1-50 | c.234G>C p.G78= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- ILK | c.1020C>T p.V340= | Silent (SNP) | VAF 75/330 reads (23%) | catalogued as rs386352317, COSV100196054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAM | c.48G>T p.G16= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- KEL | c.45C>T p.S15= | Silent (SNP) | VAF 79/277 reads (29%) | catalogued as COSV62337693; called by muse, mutect2, varscan2
- KLHL34 | c.1281C>A p.L427= | Silent (SNP) | VAF 55/156 reads (35%) | called by muse, mutect2, varscan2
- KMT2D | c.13191G>T p.G4397= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- KRIT1 | c.933A>G p.R311= | Silent (SNP) | VAF 98/372 reads (26%) | called by muse, mutect2, varscan2
- LHFPL6 | c.231C>T p.I77= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- LRRC8C | c.1452G>A p.A484= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as rs940215975; called by muse, mutect2, varscan2
- MAP10 | c.2020T>C p.L674= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- MAP1A | c.6669C>G p.A2223= | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- MARCHF8 | c.783A>G p.E261= | Silent (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2
- MAST2 | c.1753T>C p.L585= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as rs1175705507, COSV63618479; called by muse, mutect2
- MRPS18A | c.501C>A p.P167= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- MTX3 | c.387A>G p.Q129= | Silent (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2
- NPHP3 | c.120G>T p.L40= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- PCDHB15 | c.256T>C p.L86= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as rs782399044; called by muse, mutect2, varscan2
- PDZD4 | c.1995C>T p.D665= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1557075404; called by muse, mutect2, varscan2
- PRDM9 | c.705C>A p.P235= | Silent (SNP) | VAF 20/220 reads (9%) | called by mutect2, varscan2
- RNF130 | c.843C>G p.P281= | Silent (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- SALL1 | c.1926G>C p.L642= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV51763692; called by mutect2, varscan2
- SEPTIN5 | c.90G>A p.L30= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- SHISA7 | c.390C>T p.N130= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- SLC35B2 | c.1149C>T p.C383= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs766869254; called by muse, mutect2, varscan2
- SPATA31A6 | c.1725A>G p.E575= | Silent (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5574C>A p.P1858= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2853C>T p.D951= | Silent (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- SSMEM1 | c.633G>A p.A211= | Silent (SNP) | VAF 30/269 reads (11%) | catalogued as rs374890168, COSV52833115; called by muse, mutect2, varscan2
- TATDN2 | c.792G>T p.V264= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- TENM3 | c.6291G>A p.S2097= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs776630968, COSV69317553; called by muse, mutect2, varscan2
- TTYH1 | c.18C>A p.G6= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- VWA5B2 | c.618C>A p.G206= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- WASHC5 | c.1206C>T p.D402= | Silent (SNP) | VAF 94/430 reads (22%) | catalogued as rs141402708; called by muse, mutect2, varscan2
- ZNF257 | c.540A>G p.K180= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs1375440209, COSV71306203; called by muse, mutect2, varscan2
- ZNF423 | c.1794C>T p.N598= (on ENST00000563137 / NM_001379286.1; = p.N590= on NM_015069.4) | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs1469740645; called by muse, mutect2
- ZNF488 | c.159G>C p.T53= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- ZNF843 | c.645G>T p.L215= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- ZRANB2 | c.916C>A p.R306= | Silent (SNP) | VAF 36/227 reads (16%) | catalogued as COSV99639082; called by muse, mutect2, varscan2
- AC244258.1 | n.524C>T | RNA (SNP) | VAF 6/45 reads (13%) | catalogued as rs9885751; called by mutect2, varscan2
- ACER3 | c.103+7141C>T | Intron (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- ADGRE1 | c.2289+12C>T | Intron (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ATP10B | c.470+1088A>G | Intron (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- CADM1 | c.1079-12119C>T | Intron (SNP) | VAF 51/228 reads (22%) | called by muse, mutect2, varscan2
- CFH | c.1336+11087C>G | Intron (SNP) | VAF 54/163 reads (33%) | catalogued as COSV100661256; called by muse, mutect2, varscan2
- CSF2RB | c.-25T>C | 5'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ELMOD1 | c.-86+509G>C | Intron (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- FBXL16 | c.1142+13G>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- GON4L | chr1:155747574 G>A | 3'Flank (SNP) | VAF 17/219 reads (8%) | catalogued as rs781355932; called by muse, mutect2
- KCNT1 | c.3099+492G>A | Intron (SNP) | VAF 14/129 reads (11%) | catalogued as rs756827646; called by muse, mutect2, varscan2
- KLHL14 | c.-44+514C>G | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
- MLC1 | c.*18C>T | 3'UTR (SNP) | VAF 25/264 reads (9%) | catalogued as rs111797969; ClinVar: uncertain significance; called by muse, mutect2
- MYADML | n.465C>T | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs767692957; called by mutect2, varscan2
- MYO3B | c.3734-4689G>C | Intron (SNP) | VAF 27/116 reads (23%) | catalogued as COSV58696694; called by muse, mutect2, varscan2
- ODF2L | c.113+30A>T | Intron (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- OR2M1P | n.260C>A | RNA (SNP) | VAF 64/222 reads (29%) | called by muse, mutect2
- P3H1 | c.2055+115A>T | Intron (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- PRMT7 | c.133-18C>T | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as rs771503121; called by mutect2, varscan2
- RCAN1 | c.253-1441C>A | Intron (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863527 G>T | 5'Flank (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- SERGEF | c.60+111G>T | Intron (SNP) | VAF 29/145 reads (20%) | catalogued as rs1035806861; called by muse, mutect2, varscan2
- SIGMAR1 | c.151+16G>A | Intron (SNP) | VAF 32/315 reads (10%) | called by muse, mutect2, varscan2
- SLC25A13 | c.329-10756G>T | Intron (SNP) | VAF 18/66 reads (27%) | called by mutect2, varscan2
- SPATA31C2 | n.2037C>T | RNA (SNP) | VAF 58/242 reads (24%) | catalogued as rs771746656; called by mutect2, varscan2
- SPOCD1 | c.2535-129A>T | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- STXBP6 | c.155-21619A>G | Intron (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- TFR2 | c.967-19G>A | Intron (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- TMTC2 | c.83+73210C>G | Intron (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- TNXB | c.2358+1740dup | Intron (INS) | VAF 18/122 reads (15%) | called by mutect2, varscan2
- TTN | c.10360+5433C>T | Intron (SNP) | VAF 60/470 reads (13%) | catalogued as rs1020845069, COSV60436942; called by muse, mutect2, varscan2
- TTYH2 | c.129+1987C>T | Intron (SNP) | VAF 5/80 reads (6%) | catalogued as rs1253884380; called by muse, mutect2
- ZNF99 | c.*2969G>A | 3'UTR (SNP) | VAF 25/137 reads (18%) | catalogued as rs750030791; called by muse, mutect2, varscan2
- ZSCAN18 | c.49+17C>T | Intron (SNP) | VAF 10/56 reads (18%) | catalogued as rs749261842; called by muse, varscan2
